Somatic mutation profile of tumor specimen MP2PRT-PAPTVF-TMP1-A (aliquot MP2PRT-PAPTVF-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPTVF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,127 days).
Specimen MP2PRT-PAPTVF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02f902ba-d112-499d-9fc3-1d821e2e1e4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPTVF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPTVF-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b89688a6-29a6-4a5b-9913-329e99d8dfed

The open-access MAF lists 81 somatic variants for this specimen: 60 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 18, Nonsense Mutation 3, Frame Shift Ins 2, 3'Flank 2, Intron 1, Splice Site 1, Translation Start Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 142/295 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 113/196 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs782059576, COSV54352953; called by muse, mutect2, varscan2
- ANKLE1 | c.1915C>T p.R639C (on ENST00000394458; = p.R585C on NM_152363.6) | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs774145775; called by muse, mutect2, varscan2
- ARHGAP31 | c.3533C>T p.S1178L | Missense Mutation (SNP) | VAF 162/322 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51790962; called by muse, mutect2, varscan2
- CDON | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs911339564, COSV99700453; called by muse, mutect2
- CREBBP | c.4471C>G p.Q1491E | Missense Mutation (SNP) | VAF 143/350 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52120333, COSV52125130; called by muse, mutect2, varscan2
- CUTA | c.430G>A p.E144K (on ENST00000488034 / NM_001014840.2; = p.E121K on NM_015921.3) | Missense Mutation (SNP) | VAF 152/295 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs778408444; called by muse, mutect2, varscan2
- DNAH2 | c.4247C>T p.S1416L | Missense Mutation (SNP) | VAF 161/371 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101209574; called by muse, mutect2, varscan2
- FAT4 | c.8950C>G p.Q2984E | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT tolerated (0.82); PolyPhen benign (0.055); catalogued as COSV58672717; called by muse, mutect2, varscan2
- FGD1 | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 119/311 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.349); catalogued as COSV100911134; called by muse, mutect2, varscan2
- FOXO1 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 12/388 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1310591117, COSV65426799; called by muse, mutect2
- FSIP2 | c.13975G>A p.E4659K | Missense Mutation (SNP) | VAF 110/207 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV58101284; called by muse, mutect2, varscan2
- GIPC3 | c.2630C>G p.S877C | Missense Mutation (SNP) | VAF 115/253 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs755756176; called by muse, mutect2, varscan2
- GRIP2 | c.908C>T p.P303L (on ENST00000619221; = p.P206L on NM_001080423.4) | Missense Mutation (SNP) | VAF 207/419 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs1004522653; called by muse, mutect2, varscan2
- H3C4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 99/194 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV61911531, COSV61912198, COSV61912262; called by muse, mutect2, varscan2
- OR2A5 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV68738528, COSV68738927; called by muse, mutect2
- RIPK2 | c.328-1G>A p.X110_splice | Splice Site (SNP) | VAF 86/185 reads (46%) | catalogued as rs781124703; called by muse, mutect2, varscan2
- WDR64 | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 122/266 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV63793778; called by muse, mutect2, varscan2
- ZNF506 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs369665225, COSV71354205, COSV71354875; called by muse, mutect2, varscan2
- ARHGAP31 | c.2329C>A p.L777M | Missense Mutation (SNP) | VAF 136/307 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- ATP8B4 | c.3221C>G p.T1074R | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CCNF | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 112/233 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD1C | c.485_486insAT p.C163Sfs*20 | Frame Shift Ins (INS) | VAF 129/283 reads (46%) | called by mutect2, varscan2
- CD1C | c.488_489dup p.H164Vfs*19 | Frame Shift Ins (INS) | VAF 145/327 reads (44%) | called by mutect2*, pindel, varscan2*
- CDH26 | c.844_845insCCCGGG p.K281_V282insAR | In Frame Ins (INS) | VAF 86/204 reads (42%) | called by mutect2, pindel, varscan2
- CECR2 | c.761G>C p.R254T (on ENST00000342247 / NM_001290047.2; = p.R91T on NM_001290046.1) | Missense Mutation (SNP) | VAF 165/318 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, varscan2
- CFAP47 | c.8533G>C p.E2845Q | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CREBBP | c.4098C>G p.D1366E | Missense Mutation (SNP) | VAF 124/252 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ELF1 | c.1104G>C p.L368F | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ELFN1 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 230/511 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ENO3 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 125/286 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ENPP2 | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 102/218 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ETFRF1 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ETV1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 109/203 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT2 | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 184/385 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- GLRX | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 157/325 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- HUWE1 | c.7612C>T p.R2538C | Missense Mutation (SNP) | VAF 180/390 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, varscan2
- KIFC1 | c.92C>G p.S31* | Nonsense Mutation (SNP) | VAF 139/311 reads (45%) | called by muse, mutect2, varscan2
- LHFPL5 | c.492G>C p.Q164H | Missense Mutation (SNP) | VAF 145/360 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- MED13L | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 140/285 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MINK1 | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 85/196 reads (43%) | called by muse, mutect2, varscan2
- MMUT | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MYBPC2 | c.1258C>G p.Q420E | Missense Mutation (SNP) | VAF 158/306 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MYOD1 | c.740C>G p.S247W | Missense Mutation (SNP) | VAF 154/370 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKDC | c.3281C>G p.S1094C | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- RNF167 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 106/215 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNPC3 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- RYR3 | c.10315G>A p.E3439K (on ENST00000389232; = p.E3440K on NM_001036.6) | Missense Mutation (SNP) | VAF 108/227 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- SCAF11 | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 191/374 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- SLCO1C1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 136/279 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- SOAT1 | c.921C>G p.I307M | Missense Mutation (SNP) | VAF 102/272 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TAF1 | c.5269G>A p.E1757K (on ENST00000373790 / NM_138923.4; = p.E1778K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/331 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TMEM132D | c.2748A>C p.L916F | Missense Mutation (SNP) | VAF 145/304 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNXB | c.5338G>C p.E1780Q (on ENST00000647633; = p.E1533Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/283 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- TRIM66 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 128/311 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- TRPC3 | c.1235C>A p.S412* (on ENST00000379645 / NM_001366479.2; = p.S339* on NM_003305.2) | Nonsense Mutation (SNP) | VAF 12/354 reads (3%) | called by muse, mutect2
- TTN | c.7126G>C p.E2376Q (on ENST00000591111; = p.E2330Q on NM_003319.4) | Missense Mutation (SNP) | VAF 149/312 reads (48%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VN1R1 | c.981G>C p.M327I | Missense Mutation (SNP) | VAF 123/266 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFYVE26 | c.6184A>G p.T2062A | Missense Mutation (SNP) | VAF 133/263 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF439 | c.1173C>A p.F391L | Missense Mutation (SNP) | VAF 131/291 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMP10 | c.264C>T p.L88= | Silent (SNP) | VAF 129/285 reads (45%) | called by muse, mutect2, varscan2
- BTBD1 | c.69G>A p.A23= | Silent (SNP) | VAF 200/416 reads (48%) | catalogued as rs748788344; called by muse, mutect2, varscan2
- CBR1 | c.105C>G p.L35= | Silent (SNP) | VAF 208/476 reads (44%) | catalogued as COSV51738945; called by muse, mutect2, varscan2
- DIP2A | c.960G>C p.L320= | Silent (SNP) | VAF 171/368 reads (46%) | catalogued as COSV100594997; called by muse, mutect2, varscan2
- EML5 | c.822C>G p.L274= | Silent (SNP) | VAF 79/179 reads (44%) | called by muse, mutect2, varscan2
- HMGN5 | c.351A>G p.E117= | Silent (SNP) | VAF 183/355 reads (52%) | called by muse, mutect2, varscan2
- IDUA | c.699G>A p.L233= | Silent (SNP) | VAF 211/524 reads (40%) | called by muse, mutect2, varscan2
- LRRN4 | c.1914G>A p.L638= | Silent (SNP) | VAF 189/389 reads (49%) | catalogued as rs1338797461; called by muse, mutect2, varscan2
- NKX1-1 | c.597C>T p.D199= | Silent (SNP) | VAF 217/658 reads (33%) | catalogued as rs1312367054, COSV101437995; called by muse, mutect2, varscan2
- OR13C5 | c.843C>T p.F281= | Silent (SNP) | VAF 10/230 reads (4%) | catalogued as rs1297575189; called by muse, mutect2
- PPP1R32 | c.171C>T p.F57= | Silent (SNP) | VAF 151/326 reads (46%) | called by muse, mutect2, varscan2
- PRIM1 | c.213G>A p.Q71= | Silent (SNP) | VAF 95/227 reads (42%) | called by muse, mutect2, varscan2
- SCUBE2 | c.1335G>A p.V445= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as rs535859288, COSV58546948; called by muse, mutect2
- SLC30A10 | c.1309C>T p.L437= | Silent (SNP) | VAF 154/318 reads (48%) | catalogued as rs775374396; called by muse, mutect2, varscan2
- SLC7A11 | c.141G>A p.L47= | Silent (SNP) | VAF 186/359 reads (52%) | called by muse, mutect2, varscan2
- SYNPO2 | c.2130C>G p.L710= | Silent (SNP) | VAF 128/297 reads (43%) | called by muse, mutect2, varscan2
- TMEM131 | c.3705C>G p.V1235= | Silent (SNP) | VAF 140/285 reads (49%) | called by muse, mutect2, varscan2
- ZC3H14 | c.366G>A p.A122= | Silent (SNP) | VAF 128/277 reads (46%) | catalogued as rs149831438; called by muse, mutect2, varscan2
- DST | c.4297-1685C>G | Intron (SNP) | VAF 150/323 reads (46%) | called by muse, mutect2, varscan2
- IGKV4-1 | chr2:88886153 ins CCGA | 3'Flank (INS) | VAF 47/132 reads (36%) | called by mutect2, pindel, varscan2
- MYADM | chr19:53874333 C>T | 3'Flank (SNP) | VAF 19/389 reads (5%) | catalogued as rs1200411917, COSV61238483; called by muse, mutect2
